Somatic mutation profile of tumor specimen TCGA-FB-A5VM-01A (aliquot TCGA-FB-A5VM-01A-11D-A32N-08) from TCGA case TCGA-FB-A5VM, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 74.9 years (27,362 days).
Specimen TCGA-FB-A5VM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5e957ca-0cae-4c0e-a6b6-eb81662a7db0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FB-A5VM-10A (Blood Derived Normal), aliquot TCGA-FB-A5VM-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a7bc921-1f1f-426c-bf71-f552a9811828

The open-access MAF lists 58 somatic variants for this specimen: 39 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 18, Splice Site 1, Intron 1, In Frame Del 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 40/297 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.1907A>G p.N636S | Missense Mutation (SNP) | VAF 46/498 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV99943414; called by muse, mutect2
- BTN3A1 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 71/619 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV99176381; called by muse, mutect2, varscan2
- CASS4 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 47/518 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100824991; called by muse, mutect2
- CIC | c.4490A>G p.Y1497C | Missense Mutation (SNP) | VAF 58/608 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs754160310, COSV99360426, COSV99360488; called by muse, mutect2
- CSMD2 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 77/675 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as rs767673294, COSV99596547; called by muse, mutect2, varscan2
- CTTNBP2 | c.617C>T p.T206M | Missense Mutation (SNP) | VAF 53/349 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as rs747316797, COSV50394511; called by muse, mutect2, varscan2
- ELMO1 | c.1822+1G>A p.X608_splice | Splice Site (SNP) | VAF 16/162 reads (10%) | catalogued as rs1476222322, COSV100166431; called by muse, mutect2, varscan2
- FBXO3 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT tolerated, low confidence (0.37); PolyPhen possibly damaging (0.899); catalogued as COSV99682379; called by muse, mutect2
- GABRB1 | c.367T>C p.F123L | Missense Mutation (SNP) | VAF 77/637 reads (12%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.982); catalogued as COSV99783881; called by muse, mutect2, varscan2
- GALNT1 | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs368892040; called by muse, mutect2, varscan2
- GJC3 | c.834T>A p.D278E | Missense Mutation (SNP) | VAF 41/346 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as COSV100458550; called by muse, mutect2, varscan2
- GPD2 | c.1870G>T p.D624Y | Missense Mutation (SNP) | VAF 36/482 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV100133738; called by muse, mutect2
- HIVEP1 | c.974T>C p.V325A | Missense Mutation (SNP) | VAF 98/615 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV101045860; called by muse, mutect2, varscan2
- IGSF22 | c.1525G>C p.V509L | Missense Mutation (SNP) | VAF 78/592 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV100080590; called by muse, mutect2, varscan2
- INTS3 | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753722156, COSV100016625; called by muse, mutect2
- KCNN4 | c.238C>G p.H80D | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99487219; called by muse, mutect2, varscan2
- KCNQ3 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 67/649 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs141821338, COSV66469250; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIFC1 | c.1789T>C p.S597P | Missense Mutation (SNP) | VAF 46/363 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100996128; called by muse, mutect2, varscan2
- KLHL3 | c.707T>C p.M236T | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100553642; called by muse, mutect2, varscan2
- LRRC40 | c.853C>G p.L285V | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV100918874; called by muse, mutect2
- MAP3K19 | c.1145A>G p.Q382R | Missense Mutation (SNP) | VAF 49/348 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs138047676; called by muse, mutect2, varscan2
- MDN1 | c.7259G>A p.R2420Q | Missense Mutation (SNP) | VAF 41/339 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs774231669, COSV101020755, COSV101021915; called by muse, mutect2, varscan2
- OR5K3 | c.378A>G p.I126M | Missense Mutation (SNP) | VAF 150/668 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748637614, COSV101051710; called by muse, mutect2, varscan2
- PACS2 | c.290_292del p.S97del | In Frame Del (DEL) | VAF 80/425 reads (19%) | catalogued as rs782429503; called by mutect2, pindel, varscan2
- PARD6A | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 65/501 reads (13%) | catalogued as rs1488873633, COSV54671055; called by muse, mutect2, varscan2
- PHKB | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 63/449 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100068836; called by muse, mutect2, varscan2
- RAB25 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 106/660 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV63108874; called by muse, mutect2, varscan2
- RIMS2 | c.3311G>A p.R1104Q (on ENST00000666250 / NM_001348490.2; = p.R912Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057518581, COSV99211923; called by muse, mutect2, varscan2
- SCN3A | c.4120G>T p.D1374Y | Missense Mutation (SNP) | VAF 39/299 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.743); catalogued as COSV51805516, COSV99328857; called by muse, mutect2, varscan2
- SLC12A9 | c.1816G>A p.V606M | Missense Mutation (SNP) | VAF 121/808 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs368545922, COSV51935154; called by muse, mutect2, varscan2
- SLC16A10 | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 24/435 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100920997; called by muse, mutect2
- SPATA16 | c.1185A>C p.K395N | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV100651772; called by muse, mutect2, varscan2
- TBC1D32 | c.2435C>A p.P812H | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99251569; called by muse, mutect2, varscan2
- TMEM131L | c.3846G>T p.Q1282H | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); catalogued as COSV99548327; called by muse, mutect2, varscan2
- TP53 | c.102del p.L35Cfs*9 | Frame Shift Del (DEL) | VAF 132/920 reads (14%) | catalogued as COSV52833841; called by mutect2, pindel, varscan2
- TRIM42 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 78/671 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as rs777678502, COSV53880304, COSV53886166; called by muse, mutect2, varscan2
- ZBP1 | c.808A>C p.N270H | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100474088; called by muse, mutect2, varscan2
- MRC1 | c.3356C>T p.A1119V | Missense Mutation (SNP) | VAF 182/1592 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA10 | c.2166G>T p.V722= | Silent (SNP) | VAF 32/219 reads (15%) | catalogued as COSV99289467; called by muse, mutect2, varscan2
- ANO5 | c.1488A>G p.E496= | Silent (SNP) | VAF 39/345 reads (11%) | catalogued as COSV100202321; called by muse, mutect2, varscan2
- ATP2B3 | c.375G>T p.S125= | Silent (SNP) | VAF 53/172 reads (31%) | catalogued as rs782519595, COSV99686180; called by muse, mutect2, varscan2
- BRWD3 | c.4713C>T p.I1571= | Silent (SNP) | VAF 37/130 reads (28%) | catalogued as COSV100955960, COSV64746123; called by muse, mutect2, varscan2
- COL5A3 | c.5097G>A p.R1699= | Silent (SNP) | VAF 99/685 reads (14%) | catalogued as COSV99319928; called by muse, mutect2, varscan2
- COMMD5 | c.219C>T p.V73= | Silent (SNP) | VAF 36/226 reads (16%) | catalogued as COSV100296175; called by muse, mutect2, varscan2
- DUSP29 | c.444C>T p.V148= | Silent (SNP) | VAF 49/368 reads (13%) | catalogued as COSV100633428; called by muse, mutect2, varscan2
- EVC | c.1980G>A p.T660= | Silent (SNP) | VAF 45/319 reads (14%) | catalogued as rs537471996, COSV99382732; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBXO3 | c.1341A>G p.E447= | Silent (SNP) | VAF 30/243 reads (12%) | catalogued as COSV99682376; called by muse, mutect2
- IBSP | c.495C>T p.S165= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as rs200405481, COSV56896722; called by muse, mutect2, varscan2
- NEGR1 | c.1047G>A p.K349= | Silent (SNP) | VAF 32/224 reads (14%) | catalogued as COSV100166674, COSV60840769; called by muse, mutect2, varscan2
- OLFML2B | c.1896C>T p.I632= | Silent (SNP) | VAF 56/344 reads (16%) | catalogued as rs1209934689, COSV99669031; called by muse, mutect2, varscan2
- OTULINL | c.1041C>T p.N347= | Silent (SNP) | VAF 42/509 reads (8%) | catalogued as rs200729060, COSV57035076; called by muse, mutect2
- PLA2G4A | c.1194C>A p.S398= | Silent (SNP) | VAF 48/441 reads (11%) | catalogued as COSV100820769, COSV66552149; called by muse, mutect2, varscan2
- RGMA | c.393G>A p.P131= | Silent (SNP) | VAF 55/425 reads (13%) | catalogued as rs747507715, COSV61234810; called by muse, mutect2, varscan2
- RP1L1 | c.1377C>T p.T459= | Silent (SNP) | VAF 84/580 reads (14%) | catalogued as rs201173500, COSV66761545; called by muse, mutect2, varscan2
- SUMO3 | c.168G>A p.Q56= | Silent (SNP) | VAF 33/277 reads (12%) | catalogued as COSV100254540; called by muse, mutect2, varscan2
- TNRC6B | c.2616C>T p.P872= | Silent (SNP) | VAF 27/172 reads (16%) | catalogued as rs1479567266, COSV100110702; called by muse, mutect2, varscan2
- ELMOD1 | c.-86+525G>C | Intron (SNP) | VAF 12/70 reads (17%) | catalogued as COSV99760524; called by muse, mutect2
